Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A4Z5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A4Z5-01A (Primary Tumor).

Department of Cancer Pathology

Gender: M

Examination result

Clinical diagnosis (suspicion) **Melanoma of the nasal cavity right side. Malignant melanoma ulcerating.**

Material:

1) Material: nose, tumor of the nose

Histopathological Diagnosis:

Malignant melanoma of the mucous membrane of the nose pT4a, pN0.

Macroscopic description:

Surgical specimen sized 5 x 6 x 1.2cm, including cartilage and skin 3.5 x 2.5 cm in length. Tumour sized 3.5 x 3 x 1.5 cm.

Microscopic description:

Malignant melanoma of the mucous membrane of the nose. Thickness min.: 12mm.

Surgical incision lines off cancer invaded area. No signs of vascular, nerve and cartilage invasion found.

Assistant:

Assistant:

ICD-0-3

Melanoma, NOS 8720/3

Site: nose, mucosa C30.0

fw
11/11/12

Source: NCI Genomic Data Commons file f289e427-429d-4256-8841-d2a1d710100b (TCGA-D9-A4Z5.93502F24-F9FE-4978-811E-E3B7F47A7BF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).